Somatic mutation profile of tumor specimen MP2PRT-PAUBNK-TMP1-A (aliquot MP2PRT-PAUBNK-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PAUBNK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,154 days).
Specimen MP2PRT-PAUBNK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0fbd725-72f6-48ca-bd60-33fc4ec86e56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUBNK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUBNK-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04f96828-aa88-4def-897e-fddc882768ba

The open-access MAF lists 56 somatic variants for this specimen: 46 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 8, Nonsense Mutation 3, 3'Flank 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANOS1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 181/499 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as rs774940627, COSV52921411; called by muse, mutect2, varscan2
- ATRX | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.523); catalogued as COSV100969576; called by muse, mutect2, varscan2
- BMP15 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 37/505 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99399207; called by muse, mutect2
- CAVIN3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 28/878 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58269136, COSV58269396; called by muse, mutect2
- IQCE | c.699C>T p.I233= | Splice Region (SNP) | VAF 14/463 reads (3%) | catalogued as COSV58082822; called by muse, mutect2
- KAT2B | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 45/1066 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs751463932; called by muse, mutect2
- NPHS1 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs746111275, COSV62287797; called by muse, mutect2
- NRXN1 | c.4096G>C p.D1366H | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV60484702; called by muse, mutect2
- SCN1A | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 127/323 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.474); catalogued as COSV57678681; called by muse, mutect2, varscan2
- SNRPN | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57597619; called by muse, mutect2
- SPHKAP | c.3827C>T p.P1276L | Missense Mutation (SNP) | VAF 184/460 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs764243029, COSV60872489; called by muse, mutect2, varscan2
- TARM1 | c.395C>T p.S132F (on ENST00000616041 / NM_001330650.1; = p.S124F on NM_001135686.3) | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); catalogued as rs1568503573; called by muse, mutect2, varscan2
- TDRD7 | c.1316A>G p.E439G | Missense Mutation (SNP) | VAF 11/364 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100795743; called by muse, mutect2
- THOC2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs777697340; called by muse, mutect2, varscan2
- ULK4 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 140/383 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV57207203; called by muse, mutect2, varscan2
- ZNF518A | c.1235C>T p.S412L | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782556513, COSV100283423; called by muse, mutect2, varscan2
- CAPN2 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 23/389 reads (6%) | called by muse, mutect2
- CNTROB | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 52/347 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIXDC1 | c.1324G>C p.E442Q (on ENST00000440460 / NM_001037954.4; = p.E231Q on NM_033425.4) | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.278); called by muse, mutect2
- DMD | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 139/378 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.4130A>T p.N1377I | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- FAM178B | c.1619A>G p.E540G | Missense Mutation (SNP) | VAF 86/276 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- FOXO1 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FUBP3 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- GOLGA8Q | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 156/960 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- GOLIM4 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 25/500 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- HDAC1 | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- KCNH7 | c.3241C>G p.Q1081E | Missense Mutation (SNP) | VAF 95/520 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KCNK18 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 80/499 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF1A | c.3658C>T p.L1220F | Missense Mutation (SNP) | VAF 13/451 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MCF2L | c.736C>G p.Q246E (on ENST00000375608; = p.Q214E on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/673 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MED1 | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 14/459 reads (3%) | called by muse, mutect2
- NCKAP1 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 22/675 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.111); called by muse, mutect2
- PAX5 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PCDH11X | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 135/574 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLS3 | c.1589G>A p.R530K | Missense Mutation (SNP) | VAF 93/493 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRKG2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 24/600 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2
- RELA | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- SHANK1 | c.5524G>C p.E1842Q | Missense Mutation (SNP) | VAF 28/620 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.53); called by muse, mutect2
- SPP1 | c.497G>A p.G166E (on ENST00000395080 / NM_001040058.2; = p.G152E on NM_000582.2) | Missense Mutation (SNP) | VAF 49/328 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- TTN | c.71237T>G p.L23746R (on ENST00000591111; = p.L16322R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/488 reads (3%) | PolyPhen possibly damaging (0.735); called by muse, mutect2
- UBA1 | c.1677C>G p.I559M | Missense Mutation (SNP) | VAF 313/758 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- ZNF132 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF518A | c.113C>G p.S38* | Nonsense Mutation (SNP) | VAF 28/152 reads (18%) | called by muse, mutect2, varscan2
- ZNF571 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2
- ZSCAN29 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 18/559 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.353); called by muse, mutect2
- ABCA12 | c.7554C>T p.L2518= (on ENST00000272895 / NM_173076.3; = p.L2200= on NM_015657.3) | Silent (SNP) | VAF 169/409 reads (41%) | called by muse, mutect2, varscan2
- CATSPERG | c.1956G>A p.Q652= | Silent (SNP) | VAF 229/618 reads (37%) | catalogued as rs756797356; called by muse, mutect2, varscan2
- EPG5 | c.1374C>T p.L458= | Silent (SNP) | VAF 9/216 reads (4%) | catalogued as rs1170547411, COSV56350936; called by muse, mutect2
- PCDHA13 | c.1611G>A p.A537= | Silent (SNP) | VAF 43/1053 reads (4%) | catalogued as COSV56527193; called by muse, mutect2
- SCN2A | c.1764C>G p.G588= | Silent (SNP) | VAF 140/413 reads (34%) | called by muse, mutect2, varscan2
- SYNE1 | c.21210G>A p.L7070= (on ENST00000367255 / NM_182961.4; = p.L6999= on NM_033071.3) | Silent (SNP) | VAF 77/216 reads (36%) | catalogued as COSV54896490, COSV99582320; called by muse, mutect2, varscan2
- TMEM222 | c.591C>T p.I197= | Silent (SNP) | VAF 20/550 reads (4%) | called by muse, mutect2
- ZNF157 | c.1092G>C p.G364= | Silent (SNP) | VAF 163/516 reads (32%) | called by muse, mutect2, varscan2
- IBTK | c.-427G>A | 5'UTR (SNP) | VAF 20/487 reads (4%) | catalogued as rs1455131565; called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 ins TCC | 3'Flank (INS) | VAF 33/185 reads (18%) | called by mutect2, pindel, varscan2
